Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87E, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87E-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: M

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Physician(s):

DIAGNOSIS:

PROSTATE, RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON GRADE 3 + 3 = SCORE 6, PRESENT IN ALL FOUR QUADRANTS, AND INVOLVING APPROXIMATELY TEN PERCENT OF SAMPLED TISSUE (SEE SYNOPSIS)
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED
- RESECTION MARGINS FREE OF TUMOR
- MARKED CHRONIC PROSTATITIS

SEMINAL VESICLES, BILATERAL, RADICAL PROSTATECTOMY

- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, RIGHT PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN NINE LYMPH NODES (0/9)

LYMPH NODES, LEFT PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN THREE LYMPH NODES (0/3)

ICD-O-3.
Adenocarcinoma, acinar 8140/3
Site Prostate NOS C61.9
Q62.1/21/13

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up a 'prostate,' consisting of a 43 gram prostate (4 x 4 x 4 cm) with portion of bilateral seminal vesicles. Inked. Tissue taken for tumor bank. Rest for permanents," by

[page 2 of 3]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old man whose serum prostate specific antigen is 7.4 and who has Gleason 3+3 bilaterally on biopsy. Operative procedure: Radical prostatectomy.

Specimen(s) Received:

A: PROSTATE
B: LYMPH NODE, RIGHT PELVIC
C: LYMPH NODE, LEFT PELVIC

Gross Description:

The specimens are received in three formalin-filled containers, each labeled [REDACTED]. The first container is labeled "prostate." It holds a previously inked, 43 gram prostate gland measuring 4 x 4 x 4 cm. The left seminal vesicle measures 1.5 x 1 x 0.8 cm, and the right seminal vesicle measures 2.4 x 1.2 x 1.1 cm. The left and right vas deferentia measure 1.5 x 0.6 x 0.6 cm, and 1.3 x 0.6 x 0.5 cm. There are left and right lateral defects, where tissue was taken for research purposes, measuring 3.3 x 0.7 cm and 2.9 x 0.9 cm, respectively. The urethra is probe patent. The bilateral seminal vesicles are grossly normal on cut surface. Cut sections disclose a prominently nodular central zone, and spongy prostatic parenchyma at the periphery. Labeled A1 - shave bladder neck margin; A2, A3 - left and right apical margins; A4, A5 - left and right seminal vesicles; A6, A7 - left base; A8, A9 - right base; A10, A11 - left apex; A12, A13 - right apex. Jar 2.

The second container is labeled "right pelvic lymph nodes." It holds irregular fatty tissue fragments, containing palpable lymph nodes, measuring 3.7 x 3.5 x 0.5 cm in aggregate. Labeled B1, B2. Jar 0.

The third container is labeled "left pelvic lymph nodes." It holds matted lymph nodes, with surrounding fat, measuring 2.6 x 2 x 0.7 cm. Labeled C1. Jar 0.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 10

GLEASON'S GRADE

The Gleason's Grade is 3+3

TUMOR LOCATION

The location of the tumor involves the
right base
right apex
left base
left apex

PERINEURAL INVASION

[page 3 of 3]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Perineural Invasion is identified

VASCULAR INVASION

Vascular invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is absent

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

All sampled surgical margins are free of tumor

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows chronic prostatitis

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Right pelvic: 0/9

Left pelvic: 0/3

PRIMARY TUMOR (T)

Tumor involves both lobes (T2c)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

No distant metastasis reportedly present (M0)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T2/N0/M0/Gleason score 6 (Stage II)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available on-line on

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file b1b9e559-6507-444a-bf22-b21b0908c109 (TCGA-VP-A87E.6B46F895-B5CD-40B8-8962-AA8DF2505446.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).